Gene-level copy-number profile of tumor specimen C3N-02088-04 from CPTAC case C3N-02088, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 60.3 years (22,039 days).
Specimen C3N-02088-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ae2cfc26-8510-4f80-922c-ea820cf5d8bc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02088-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/2ef6e206-368e-4a24-aabe-480ccab97b65

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 789; copy number 2: 24,069; copy number 3: 22,356; copy number 4: 8,717; copy number 5: 1,938; copy number 6: 316; copy number 7: 100; copy number 8: 74; copy number 9: 39; copy number 10: 186; copy number 11: 53; copy number 12: 48; copy number 13: 52; copy number 14: 14; copy number 16: 10; copy number 20: 46; copy number 23: 27.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,321,300–27,230,174, 71 genes (broad region; genes not listed).
- chr22:15,282,557–15,350,043, 5 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 649 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:95,310,928–96,584,727, 14 genes, copy number 8: LINC01760, LINC01650, AL445218.1, LINC01761, LINC02607, AL683887.1, LINC02790, RNU1-130P, LINC01787, AC092393.1, UBE2WP1, EEF1A1P11, RN7SL831P, NDUFS5P2.
- chr7:57,060,590–62,275,678, 55 genes, copy number 7: PHKG1P4, AC122133.1, ZNF479, AC099654.11, AC099654.2, MTATP6P8, MTCO3P10, MTND4LP32, MTND4P4, MTND5P6, MTCYBP29, GUSBP10, MTND1P4, MTND2P6, MTCO1P10, MTCO2P10, MTCO3P4, AC099654.7, MTND4P5, MTND5P7, MTCYBP5, GUSBP12, AC099654.1, RNU7-157P, AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:152,435,695–152,447,150, 2 genes, copy number 8 (within-gene range 4–8): FABP5P3, CCT8L1P.
- chr8:39,451,045–39,522,852, 1 gene, copy number 10: ADAM3A.
- chr8:41,490,396–42,897,290, 43 genes, copy number 7 (within-gene range 5–7): GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469.
- chr9:4,553,386–6,197,248, 51 genes, copy number 8–12 (within-gene range 4–12): SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274, AL162253.2, PDCD1LG2, AL162253.1, RIC1, AL136980.1, ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1, GTF3AP1.
- chr9:7,477,045–7,478,320, 1 gene, copy number 8: RPL4P5.
- chr9:10,613,202–10,632,203, 2 genes, copy number 8: PTPRD-AS2, AL135790.1.
- chr12:53,935,328–54,125,992, 27 genes, copy number 8 (within-gene range 5–8): HOXC13-AS, HOXC13, HOXC12, HOTAIR, AC012531.5, AC012531.7, AC012531.4, AC012531.6, HOXC11, HOXC-AS3, HOXC10, AC012531.3, HOXC6, MIR196A2, HOXC-AS2, HOXC9, HOXC-AS1, HOXC8, HOXC4, AC012531.2, AC012531.1, HOXC5, MIR615, FLJ12825, AC023794.3, AC023794.2, FAM242C.
- chr12:55,221,025–55,427,192, 16 genes, copy number 11: OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr12:58,872,149–60,269,686, 16 genes, copy number 9: LRIG3, AC068305.2, RPS6P22, AC068305.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1.
- chr12:61,600,067–73,846,188, 234 genes, copy number 8–23 (broad region; genes not listed).
- chr16:31,355,134–31,382,999, 2 genes, copy number 7: ITGAX, AC093520.2.
- chr19:31,149,979–31,349,436, 1 gene, copy number 9 (within-gene range 6–9): TSHZ3.
- chr19:31,348,881–32,485,895, 17 genes, copy number 9: AC025809.1, AC025809.2, AC008992.1, AC008794.1, LINC02841, AC011525.1, AC011525.2, RNA5SP471, RNU6-967P, LINC01837, LINC01533, LINC01782, AC011518.1, RNA5SP472, ZNF507, AC007773.1, DPY19L3.
- chr19:34,533,427–37,248,738, 167 genes, copy number 10–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
